CPTAC case C3N-01802 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2c779d6c-f661-4621-9e3b-f9705da342a1

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1932; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 85.0 years (31,052 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 775 days (2.1 years); Progression or recurrence: yes; Days to recurrence: 598 days (1.6 years); Days to last follow up: 775 days (2.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.8 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 5; Margin status: Involved.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 401 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 775 days (2.1 years); Disease response: With Tumor.
- Days to follow up: 775 days (2.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 598 days (1.6 years).

Other clinical attributes
- Weight: 64.3 kg; Height: 162.6 cm; BMI: 24.32.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01802-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 35 days; Initial weight: 204 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01802-21: Section location: Extensively involved entire endometrial lining; Percent tumor nuclei: 95; Percent necrosis: 5.
- Sample C3N-01802-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 35 days; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01802-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 35 days; Method of sample procurement: Blood Draw.
- Sample C3N-01802-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
